Somatic mutation profile of tumor specimen C3L-01302-03 (aliquot CPT0063630006) from CPTAC case C3L-01302, project CPTAC-3 (Kidney — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Dead; Primary diagnosis: Renal cell carcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage III; Tumor grade: G4; Age at diagnosis: 71.4 years (26,084 days).
Specimen C3L-01302-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1bca37eb-c15b-4285-a947-4beffad46e27.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-01302-31 (Blood Derived Normal), aliquot CPT0065290002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/dd7b6522-a86b-42b6-ac7f-0e4193c0decc

The open-access MAF lists 63 somatic variants for this specimen: 50 protein-altering or splice-affecting, 5 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 39, Silent 5, Frame Shift Del 5, Intron 5, Splice Region 2, Nonsense Mutation 2, 5'Flank 2, In Frame Ins 1, Frame Shift Ins 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- USH2A | c.1481A>G p.Y494C | Missense Mutation (SNP) | VAF 29/174 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); catalogued as rs898430789; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- C20orf27 | c.398G>A p.R133H (on ENST00000379772 / NM_001258429.2; = p.R158H on NM_001039140.3) | Missense Mutation (SNP) | VAF 62/191 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as rs374709259; called by muse, mutect2, varscan2
- CPNE2 | c.1558G>T p.A520S | Missense Mutation (SNP) | VAF 17/73 reads (23%) | SIFT tolerated (0.1); PolyPhen benign (0.139); catalogued as COSV51963475; called by muse, mutect2, varscan2
- CRTAM | c.898A>G p.I300V | Missense Mutation (SNP) | VAF 20/116 reads (17%) | SIFT tolerated (0.95); PolyPhen benign (0.01); catalogued as rs147039129; called by muse, mutect2, varscan2
- GRAMD1A | c.1138G>A p.A380T | Missense Mutation (SNP) | VAF 37/215 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.622); catalogued as rs948089718, COSV58766283; called by muse, mutect2, varscan2
- LRRC61 | c.173T>G p.L58R | Missense Mutation (SNP) | VAF 71/405 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs779012504; called by muse, mutect2, varscan2
- MDGA1 | c.1285G>A p.V429I | Missense Mutation (SNP) | VAF 14/75 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.086); catalogued as rs368627991; called by muse, mutect2, varscan2
- MSH2 | c.1622C>T p.T541I | Missense Mutation (SNP) | VAF 13/91 reads (14%) | SIFT tolerated (0.48); PolyPhen benign (0.006); catalogued as rs864622079; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PCDH19 | c.1548C>G p.Y516* | Nonsense Mutation (SNP) | VAF 100/626 reads (16%) | catalogued as COSV55262683; called by muse, mutect2, varscan2
- PLPPR4 | c.1944G>T p.K648N | Missense Mutation (SNP) | VAF 32/179 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.142); catalogued as COSV100926788; called by muse, mutect2, varscan2
- ROMO1 | c.185A>T p.Q62L | Missense Mutation (SNP) | VAF 56/361 reads (16%) | SIFT tolerated (0.11); PolyPhen benign (0.067); catalogued as rs757323572; called by muse, mutect2, varscan2
- SPHKAP | c.3676C>T p.P1226S | Missense Mutation (SNP) | VAF 31/115 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.223); catalogued as rs1195536945; called by muse, mutect2, varscan2
- SUZ12 | c.1960C>G p.R654G | Missense Mutation (SNP) | VAF 13/57 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.577); catalogued as COSV100497034, COSV59498640; called by muse, mutect2, varscan2
- TERT | c.2086C>T p.R696C | Missense Mutation (SNP) | VAF 33/248 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as rs973201915, COSV57206668; called by muse, mutect2, varscan2
- TNRC18 | c.6280G>A p.G2094R | Missense Mutation (SNP) | VAF 77/262 reads (29%) | SIFT tolerated (0.08); PolyPhen benign (0.013); catalogued as rs543731403; called by muse, mutect2, varscan2
- UBXN8 | c.665C>T p.T222M | Missense Mutation (SNP) | VAF 16/74 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs201673016; called by muse, mutect2
- ADAP2 | c.681_697del p.L228Afs*9 | Frame Shift Del (DEL) | VAF 17/225 reads (8%) | called by mutect2, pindel
- ARHGEF10 | c.1182T>A p.N394K (on ENST00000398564; = p.N369K on NM_014629.4) | Missense Mutation (SNP) | VAF 50/338 reads (15%) | SIFT tolerated (0.52); PolyPhen benign (0.077); called by muse, mutect2, varscan2
- BMP7 | c.639C>A p.S213R | Missense Mutation (SNP) | VAF 46/244 reads (19%) | SIFT tolerated (0.33); PolyPhen benign (0.215); called by muse, mutect2, varscan2
- CCIN | c.221C>A p.T74N | Missense Mutation (SNP) | VAF 100/468 reads (21%) | SIFT tolerated (0.13); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CDC42SE1 | c.136G>A p.E46K | Missense Mutation (SNP) | VAF 38/191 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.081); called by muse, mutect2, varscan2
- CRCT1 | c.152G>A p.G51D | Missense Mutation (SNP) | VAF 46/311 reads (15%) | PolyPhen possibly damaging (0.873); called by muse, mutect2, varscan2
- CRYGC | c.462C>A p.C154* | Nonsense Mutation (SNP) | VAF 62/269 reads (23%) | called by muse, mutect2, varscan2
- CTDSPL | c.123C>A p.S41R | Missense Mutation (SNP) | VAF 19/79 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.013); called by muse, mutect2
- CXorf21 | c.427_430del p.D143Ffs*13 | Frame Shift Del (DEL) | VAF 27/111 reads (24%) | called by mutect2, pindel, varscan2
- DGKI | c.2455C>G p.L819V | Missense Mutation (SNP) | VAF 11/244 reads (5%) | SIFT tolerated (0.32); PolyPhen benign (0.015); called by muse, mutect2
- EGR4 | c.246del p.P83Hfs*71 | Frame Shift Del (DEL) | VAF 33/118 reads (28%) | called by mutect2, pindel, varscan2
- EIF3L | c.1469T>G p.L490R | Missense Mutation (SNP) | VAF 31/252 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FAM133A | c.50C>A p.A17D | Missense Mutation (SNP) | VAF 20/74 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.948); called by muse, mutect2, varscan2
- FAM174C | c.200del p.G67Afs*4 | Frame Shift Del (DEL) | VAF 58/335 reads (17%) | called by mutect2, pindel, varscan2
- FAM53A | c.491G>T p.S164I | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT tolerated (0.21); PolyPhen benign (0.288); called by muse, mutect2, varscan2
- FREM2 | c.407T>C p.V136A | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- HLA-DRA | c.682C>A p.L228M | Missense Mutation (SNP) | VAF 13/92 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- KIAA0232 | c.1159T>C p.Y387H | Missense Mutation (SNP) | VAF 26/190 reads (14%) | SIFT tolerated (0.54); PolyPhen benign (0); called by muse, mutect2, varscan2
- KIDINS220 | c.3428C>G p.P1143R | Missense Mutation (SNP) | VAF 18/69 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.215); called by muse, varscan2
- KIF14 | c.4918_4919insTTT p.E1639_C1640insF | In Frame Ins (INS) | VAF 17/77 reads (22%) | called by mutect2, pindel, varscan2
- LAMB4 | c.3620G>C p.R1207T | Missense Mutation (SNP) | VAF 95/321 reads (30%) | SIFT tolerated (0.35); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- LILRB1 | c.1399A>T p.T467S (on ENST00000427581; = p.T431S on NM_006669.6) | Missense Mutation (SNP) | VAF 9/67 reads (13%) | SIFT tolerated (0.31); PolyPhen benign (0.076); called by muse, mutect2, varscan2
- LILRB1 | c.1400C>T p.T467I (on ENST00000427581; = p.T431I on NM_006669.6) | Missense Mutation (SNP) | VAF 9/69 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.059); called by muse, mutect2, varscan2
- MFN2 | c.2070-6C>T | Splice Region (SNP) | VAF 108/519 reads (21%) | called by muse, mutect2, varscan2
- NPY | c.55C>T p.L19F | Missense Mutation (SNP) | VAF 21/386 reads (5%) | SIFT tolerated (0.05); PolyPhen benign (0.012); called by muse, mutect2
- PBRM1 | c.2673dup p.S892Qfs*9 | Frame Shift Ins (INS) | VAF 30/97 reads (31%) | called by mutect2, pindel, varscan2
- PTCRA | c.489del p.F163Lfs*5 | Frame Shift Del (DEL) | VAF 103/447 reads (23%) | called by mutect2, pindel, varscan2
- PTPRK | c.3854A>C p.Y1285S (on ENST00000368215 / NM_001291984.2; = p.Y1286S on NM_002844.4) | Missense Mutation (SNP) | VAF 24/119 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- SHROOM4 | c.3026C>T p.A1009V | Missense Mutation (SNP) | VAF 45/297 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0); called by muse, mutect2, varscan2
- TBR1 | c.820T>G p.C274G | Missense Mutation (SNP) | VAF 27/123 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- TJP3 | c.348T>A p.D116E | Missense Mutation (SNP) | VAF 26/96 reads (27%) | SIFT tolerated (0.25); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TUBAL3 | c.396G>T p.L132= | Splice Region (SNP) | VAF 14/43 reads (33%) | called by muse, mutect2
- WNK2 | c.2447C>A p.A816D | Missense Mutation (SNP) | VAF 8/115 reads (7%) | SIFT tolerated (0.19); PolyPhen benign (0.03); called by muse, mutect2
- XRN1 | c.3553T>G p.L1185V | Missense Mutation (SNP) | VAF 74/397 reads (19%) | SIFT tolerated (0.12); PolyPhen benign (0.406); called by muse, mutect2, varscan2
- C10orf90 | c.882C>T p.L294= | Silent (SNP) | VAF 78/354 reads (22%) | called by muse, mutect2, varscan2
- C1QTNF2 | c.870C>T p.D290= (on ENST00000393975; = p.D245= on NM_031908.6 and 1 other RefSeq transcript) | Silent (SNP) | VAF 122/378 reads (32%) | catalogued as rs201096732; called by muse, mutect2, varscan2
- DAGLA | c.2085G>A p.Q695= | Silent (SNP) | VAF 34/228 reads (15%) | called by muse, mutect2
- LRATD1 | c.729C>T p.Y243= | Silent (SNP) | VAF 11/39 reads (28%) | catalogued as rs753768386; called by muse, mutect2, varscan2
- TOP1MT | c.1425G>A p.T475= | Silent (SNP) | VAF 59/291 reads (20%) | catalogued as rs201125639; called by muse, mutect2, varscan2
- LINC01558 | n.403G>A | RNA (SNP) | VAF 22/136 reads (16%) | called by muse, varscan2
- LRP1 | c.841+3529T>A | Intron (SNP) | VAF 10/36 reads (28%) | called by muse, varscan2
- MPRIP | c.2163+5050G>T | Intron (SNP) | VAF 7/168 reads (4%) | called by muse, mutect2
- NLE1 | c.18+24G>A | Intron (SNP) | VAF 67/207 reads (32%) | called by muse, mutect2, varscan2
- RNF32 | chr7:156640326 A>T | 5'Flank (SNP) | VAF 54/171 reads (32%) | called by muse, mutect2, varscan2
- SLC11A2 | c.49+1830G>C | Intron (SNP) | VAF 46/236 reads (19%) | catalogued as rs1356514562; called by muse, mutect2, varscan2
- VPS35 | c.3+32C>G | Intron (SNP) | VAF 47/286 reads (16%) | called by muse, mutect2, varscan2
- WT1 | chr11:32438614 A>G | 5'Flank (SNP) | VAF 115/507 reads (23%) | called by muse, mutect2, varscan2
